Surgical pathology report (de-identified scan), TCGA case TCGA-KM-8477, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-8477-01A (Primary Tumor).

[page 1 of 3]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Surgical Pathology Report

PATIENT:
ACCOUNT#:
DOB:
AGE:
ATTENDING:
REQUESTING:
CONTACT NO:
COPIES TO:

MRN:
RECEIVED DATE:
PROCEDURE DATE:
SIGN-OUT DATE:
LOCATION:

ROOM:

DIAGNOSIS:

1. Kidney, right "base of tumor" (excision): Kidney parenchyma, no tumor seen.
2. Kidney, right "right renal mass" (excision): Chromophobe renal cell carcinoma (3.8cm); inked perinephric fat is not involved. Areas of necrosis and hemorrhage, see Note.
3. Soft tissue, "fat over tumor" (excision): Fibroadipose tissue, no tumor seen.

NOTE: The tumor cells are positive for c-kit (CD117). [REDACTED] reviewed the case and concurs with the diagnosis.

The immunoperoxidase tests performed here were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: Right renal mass s/p right partial nephrectomy
Specimen Taken For [REDACTED]

PROCEDURE: Pre-Operative Diagnosis: Right renal mass Post-Operative Diagnosis:
Right renal mass Operative Findings: 3x4 cm right lower pole renal
mass excised with negative margins on frozen section

Patient Identification

Surgical Pathology Report

[page 2 of 3]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

SPECIMENS SUBMITTED: 1. BIOPSY, NOS, LEVEL 5 SECTIONING, Base of tumor (1FS)
2. KIDNEY, RIGHT, Renal mass
3. FAT, Over tumor

INTRAOPERATIVE CONSULTATION:

1FS Diagnosis: Kidney parenchyma, no tumor seen.

This frozen diagnosis was performed by [REDACTED]

GROSS DESCRIPTION:

Received are 3 containers labeled with the patient's name, medical record number, and further described as follows:

1. Received from the OR labeled with the patient's name, medical record number and "base of tumor" is a fragment of pink/tan soft tissue measuring 0.5 x 0.3 x 0.2 cm. It is frozen as 1FS1. Per OR, the specimen is margin, question of presence of tumor.

In Surgical Pathology, the remainder of the tissue received and the contents of the contents in the green cassette labeled 1FS1 is transferred to an orange cassette labeled [REDACTED] for serial 5 sectioning.

2. The specimen is labeled "right renal mass" consists of an unoriented piece of kidney with attached mass which has a thin fibrous capsule surrounding the mass. The specimen weighs 31.9 grams and measures 4.5 x 3.9 x 3.7 cm. Surgical margins are inked blue and the specimen is bivalved brown thick material consistent with old blood and tan/red solid areas toward the periphery. 5% is procured for TIL for research. The remainder is sent to Surgical Pathology. The procurement and this initial description were performed by [REDACTED]

In Surgical Pathology, the remainder of the tissue received. It is consistent with the above description. The cystic area measures 3.8x3.8x3.5 cm. In the lumen of the cyst, there are several solid mahogany brown areas, the largest nodule measuring 1.3 cm in diameter. Representative sections from the nodules are placed in white cassettes labeled [REDACTED]. Other hemorrhagic cyst wall areas in 2D.

3. "Fat over tumor". The specimen consists of multiple fibroadipose tissue fragments measuring in aggregate 1.5 x 1.5 x 1.5 cm. The entire specimen is submitted into white cassettes labeled [REDACTED] and B.

Gross dictated by [REDACTED]

No consultants

Patient Identification

Surgical Pathology Report

[page 3 of 3]
Patient Identification

Surgical Pathology Report

Source: NCI Genomic Data Commons file 47a381b5-976d-4b0f-b1f1-19f921a37882 (TCGA-KM-8477.E3B2F16E-B369-4939-B4EB-ABCEF674F3FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).